CPTAC case C3N-03792 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2890504d-6736-4b86-bdeb-0b9ab7efb9eb

Demographics
Sex at birth: male; Race: white; Year of birth: 1979; Vital status: Dead; Days to death: 87 days; Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Occipital lobe; Age at diagnosis: 38.5 years (14,044 days); Year of diagnosis: 2018; Days to last known disease status: 87 days; Days to last follow up: 87 days.
   Pathology details: Greatest tumor dimension: 4 cm.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 87.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03792-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -17 days; Initial weight: 379 mg; Time between excision and freezing: 9 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03792-21: Section location: Occipital Lobe; Percent tumor nuclei: 60; Percent necrosis: 55.
- Sample C3N-03792-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -17 days; Method of sample procurement: Blood Draw.
